Gene-level copy-number profile of tumor specimen TCGA-06-0414-01A from TCGA case TCGA-06-0414, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.6 years (23,215 days).
Specimen TCGA-06-0414-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.6ea9ccd8-d0cc-44b3-b54a-bf89e54c174b.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,165 have no estimate.
https://portal.gdc.cancer.gov/files/d7f2ada0-2a17-4773-bfe6-a7e672d085bb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 1: 2; copy number 2: 6,915; copy number 3: 17,035; copy number 4: 31,442.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-06-0414-01): tumor purity 0.75, ploidy 3.4, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:3,433,508–4,682,722, 19 genes (within-gene range 0–2): LINC02669, AL357833.1, AL450322.2, AL450322.1, KLF6, AL513303.1, LINC02639, LINC02660, MIR6078, AC025822.1, AC025822.2, LINC00702, LINC00703, AC022535.1, AC022535.3, AC022535.2, RNU6-163P, MANCR, LINC00705.
- chr10:5,154,140–5,185,187, 1 gene: AKR1C8P.
- chr10:87,500,337–87,971,930, 14 genes (within-gene range 0–2): AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2.
- chr10:88,259,129–88,584,530, 2 genes (within-gene range 0–2): AL353149.1, RNLS.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–2): RB1.
- chr13:48,488,963–49,793,307, 27 genes: RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
